Somatic mutation profile of tumor specimen TCGA-DD-A73B-01A (aliquot TCGA-DD-A73B-01A-12D-A32G-10) from TCGA case TCGA-DD-A73B, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.3 years (26,390 days).
Specimen TCGA-DD-A73B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0405668-56fa-41c5-8ef8-1da869c6d50d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73B-10A (Blood Derived Normal), aliquot TCGA-DD-A73B-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5233ce9c-a2f2-4392-94e1-ea62401f5668

The open-access MAF lists 84 somatic variants for this specimen: 67 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 15, Nonsense Mutation 5, Splice Site 2, RNA 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052626, CM154627, COSV60433067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.461C>G p.T154R (on ENST00000354273; = p.T210R on NM_016234.3) | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV61129974; called by muse, mutect2, varscan2
- ALMS1 | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52507388; called by muse, mutect2, varscan2
- ARID2 | c.4245T>G p.I1415M | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.033); catalogued as COSV57601109; called by muse, mutect2, varscan2
- ATP2B4 | c.2383A>C p.K795Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58176387; called by muse, mutect2, varscan2
- ATP2C1 | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100146971; called by muse, mutect2
- C3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55571353; called by muse, mutect2, varscan2
- C4B | c.3824A>C p.H1275P | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV70313338; called by mutect2, varscan2
- C5orf34 | c.1556T>C p.I519T | Missense Mutation (SNP) | VAF 164/391 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs145050535, COSV60928863; called by muse, mutect2, varscan2
- C9 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as COSV54675861; called by muse, mutect2, varscan2
- CACNG1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs551549167, COSV56826360; called by muse, mutect2, varscan2
- CALCOCO1 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 54/129 reads (42%) | catalogued as COSV50412969; called by muse, mutect2, varscan2
- CCDC146 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 133/429 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV53546704; called by muse, mutect2, varscan2
- CCR2 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV52748245; called by muse, mutect2, varscan2
- CD5 | c.56-2A>G p.X19_splice | Splice Site (SNP) | VAF 13/22 reads (59%) | catalogued as rs1372431875, COSV61718163; called by muse, mutect2, varscan2
- CD9 | c.325T>G p.W109G | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50530130; called by muse, mutect2, varscan2
- CHMP6 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV57327213; called by muse, mutect2, varscan2
- CHST11 | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV57986045; called by muse, mutect2, varscan2
- CHURC1 | c.418T>C p.*140Qext*20 (on ENST00000549115 / NM_001204063.1; = p.*141Qext*20 on NM_145165.3) | Nonstop Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as COSV63036111; called by muse, mutect2, varscan2
- CYP2R1 | c.454A>C p.K152Q | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV58127229; called by muse, mutect2, varscan2
- DNAH5 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV54217296, COSV99450822; called by muse, mutect2, varscan2
- DOCK4 | c.3007A>G p.I1003V | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1321989834, COSV70235428; called by muse, mutect2, varscan2
- DOT1L | c.2469G>T p.M823I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs562099241, COSV67109040; called by muse, mutect2, varscan2
- DPP6 | c.1703C>G p.T568R (on ENST00000377770 / NM_001364500.2; = p.T506R on NM_001936.5) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59606402; called by muse, mutect2, varscan2
- E2F3 | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60896981; called by muse, mutect2, varscan2
- ECPAS | c.5441C>T p.A1814V | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as rs1213679636, COSV52195110; called by muse, mutect2, varscan2
- EDEM2 | c.1338C>G p.F446L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.942); catalogued as COSV63259487, COSV63259635; called by muse, mutect2, varscan2
- EHBP1L1 | c.4388G>T p.R1463L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58572353; called by muse, mutect2, varscan2
- EMILIN2 | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54422582; called by muse, mutect2, varscan2
- EZHIP | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as rs1275500691, COSV100539658, COSV100539891; called by muse, mutect2, varscan2
- FAM47B | c.1768A>T p.I590F | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61453253; called by muse, mutect2, varscan2
- FCGR2A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV54837700; called by muse, mutect2, varscan2
- FCGR3B | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 94/175 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54209568; called by muse, mutect2, varscan2
- GPI | c.1474+1G>T p.X492_splice | Splice Site (SNP) | VAF 55/145 reads (38%) | catalogued as COSV55825095; called by muse, mutect2, varscan2
- GPX1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV69042192; called by muse, mutect2, varscan2
- GRIA2 | c.1381T>A p.Y461N | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52387249; called by muse, mutect2, varscan2
- GRK2 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV57951316; called by muse, mutect2, varscan2
- INHBA | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV54220749, COSV54225158; called by muse, mutect2, varscan2
- ITGA3 | c.2669T>C p.L890P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50308341; called by muse, mutect2, varscan2
- MAN2A1 | c.2571A>G p.I857M | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1416340913, COSV54850167; called by muse, mutect2, varscan2
- MYCBP2 | c.10972A>G p.S3658G (on ENST00000357337; = p.S3696G on NM_015057.5) | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV62015061; called by muse, mutect2, varscan2
- MYO16 | c.4600G>A p.G1534R | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as COSV62748510; called by muse, mutect2, varscan2
- MYO9B | c.2228A>T p.H743L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs1346303616, COSV68278324; called by muse, mutect2, varscan2
- NPFFR1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53332765; called by muse, mutect2, varscan2
- OLFML2A | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV56582796; called by muse, varscan2
- OLFML2A | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as COSV56582813; called by muse, varscan2
- OR51F1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs753769597, COSV58579300; called by muse, mutect2, varscan2
- PASK | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.19); PolyPhen benign (0.342); catalogued as COSV52148496; called by muse, mutect2, varscan2
- PIWIL4 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV54408842, COSV54409016; called by muse, mutect2, varscan2
- PRLHR | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53303512; called by muse, mutect2, varscan2
- SCAND1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV60004742; called by muse, mutect2, varscan2
- SCN1A | c.2293G>T p.V765L (on ENST00000303395 / NM_001202435.3; = p.V754L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57666152, COSV57675585; called by muse, mutect2, varscan2
- SEMA6D | c.1002T>A p.D334E | Missense Mutation (SNP) | VAF 78/96 reads (81%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV60375415; called by muse, mutect2, varscan2
- SMAD5 | c.1084T>C p.F362L | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV72597071; called by muse, mutect2, varscan2
- SOS1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 79/86 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs775052125, COSV67674707; called by muse, mutect2, varscan2
- SPINK6 | c.184T>C p.C62R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57777900; called by muse, mutect2, varscan2
- SRRT | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV61451816; called by muse, mutect2, varscan2
- TACR1 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as COSV59480713; called by muse, mutect2, varscan2
- TMEM174 | c.527T>A p.M176K | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as COSV57113493; called by muse, mutect2, varscan2
- USP26 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs764088622, CM164474, COSV63708038; called by muse, mutect2, varscan2
- YWHAH | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV50708277; called by muse, varscan2
- ZACN | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV58035603; called by muse, mutect2, varscan2
- ZFPM2 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs575054307, COSV101023590, COSV65873026; ClinVar: benign; called by muse, mutect2, varscan2
- ZNF221 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52108865; called by muse, mutect2, varscan2
- ZNF584 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59722121; called by muse, mutect2, varscan2
- ZNF595 | c.1745A>G p.H582R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369572114; called by muse, mutect2, varscan2
- ZNF764 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53221483; called by muse, mutect2, varscan2
- ACAN | c.4581G>A p.R1527= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as COSV61358843; called by muse, mutect2, varscan2
- BCL6 | c.513C>T p.S171= | Silent (SNP) | VAF 32/34 reads (94%) | catalogued as rs751896144, COSV51651090; called by muse, mutect2, varscan2
- CD4 | c.1125G>C p.S375= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs782556070, COSV50590060; called by muse, mutect2
- FASN | c.3324G>A p.E1108= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV60752806; called by muse, mutect2, varscan2
- KCNK18 | c.1023C>G p.S341= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV57971497; called by muse, mutect2, varscan2
- KIF16B | c.1653T>C p.F551= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs1568943561, COSV61704588; called by muse, mutect2, varscan2
- LYST | c.7605T>C p.N2535= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV101087905, COSV67705792; called by muse, mutect2, varscan2
- NAGS | c.978C>T p.S326= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV52813112; called by muse, mutect2, varscan2
- PRKAG3 | c.1398C>T p.G466= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs781471980, COSV52101428; called by muse, mutect2, varscan2
- RABEPK | c.924T>C p.A308= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as COSV52334894; called by muse, mutect2, varscan2
- RANBP2 | c.3990T>C p.D1330= | Silent (SNP) | VAF 40/44 reads (91%) | catalogued as COSV51699181; called by muse, mutect2, varscan2
- RELN | c.5442T>C p.P1814= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV58995486; called by muse, mutect2, varscan2
- SEMA3E | c.924A>G p.E308= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV57085478; called by muse, mutect2, varscan2
- TMEM42 | c.375G>A p.Q125= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as rs376440839; called by muse, mutect2, varscan2
- ZAN | c.1758C>A p.V586= | Silent (SNP) | VAF 87/154 reads (56%) | catalogued as COSV61807635; called by muse, mutect2, varscan2
- C11orf40 | n.631A>G | RNA (SNP) | VAF 16/69 reads (23%) | catalogued as COSV56890324; called by muse, mutect2, varscan2
- DMKN | c.1239+283C>T | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs1163746870, COSV60085702; called by muse, mutect2
